MMRF case MMRF_1678 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/af66ead1-8263-4fe9-b34d-6e4350a185fb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 231 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.7 years (29,466 days); Days to last known disease status: 231 days; Days to last follow up: 231 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 212 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 231 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 231.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 3): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.6 mg/dL; Immunoglobulin G 3.7 g/L; Immunoglobulin A 59 g/L; Immunoglobulin M 1.15 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.9 mmol/L; Albumin 25 g/L; Total Protein 9.5 g/dL; Glucose 5.83 mmol/L.
- Day 72 (ECOG 0): Immunoglobulin G 3.29 g/L; Immunoglobulin A 22.6 g/L; Immunoglobulin M 0.659 g/L; Lactate Dehydrogenase 2.05 µkat/L; Creatinine 84.9 µmol/L; Calcium 2.3 mmol/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 183 (ECOG 1): M Protein 1.5 g/dL; Immunoglobulin G 4.27 g/L; Immunoglobulin A 16.7 g/L; Immunoglobulin M 0.658 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.13 ×10⁹/L; Absolute Neutrophil 4.24 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 77.8 µmol/L; Calcium 2.4 mmol/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -8: Weight: 75 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1678_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1678_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
